Somatic mutation profile of tumor specimen MP2PRT-PAVJIY-TBP1-A (aliquot MP2PRT-PAVJIY-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVJIY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,328 days).
Specimen MP2PRT-PAVJIY-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c2a90da-7efb-4115-9b58-4a0c609d60fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVJIY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVJIY-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd66afc1-1dc1-457a-bf0c-25c0a0454939

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1780T>A p.F594I | Missense Mutation (SNP) | VAF 29/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54051445, COSV54057242, COSV54063712; called by muse, mutect2
- NLRP5 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 34/471 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs749462086, COSV66764108; called by muse, mutect2
- PTAR1 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 48/632 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.572); catalogued as rs762177997, COSV61208157; called by muse, mutect2
- BNIPL | c.372C>T p.D124= | Silent (SNP) | VAF 137/424 reads (32%) | catalogued as rs144241818; called by muse, mutect2, varscan2
- LAMA1 | c.3219C>A p.A1073= | Silent (SNP) | VAF 143/589 reads (24%) | called by muse, mutect2, varscan2
- SLC35F4 | c.1008G>A p.A336= (on ENST00000339762 / NM_001352015.2; = p.A300= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/337 reads (24%) | catalogued as rs370452519, COSV100334105; called by muse, mutect2, varscan2
- TPTE | c.33G>A p.A11= | Silent (SNP) | VAF 40/388 reads (10%) | catalogued as rs757219554; called by muse, mutect2, varscan2
- WWC3 | c.2925G>A p.A975= | Silent (SNP) | VAF 209/811 reads (26%) | catalogued as rs1289224294, COSV101081364; called by muse, mutect2, varscan2
